Somatic mutation profile of tumor specimen ALCH-B4EP-TTP1-A (aliquot ALCH-B4EP-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4EP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.2 years (23,449 days).
Specimen ALCH-B4EP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6c42ad3-d7dc-46b4-a8ee-4f545015afd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4EP-NB1-A (Blood Derived Normal), aliquot ALCH-B4EP-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e9176e6-df6d-4d3c-bc3f-eb9e490306e0

The open-access MAF lists 45 somatic variants for this specimen: 26 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 15, In Frame Ins 2, Intron 2, Splice Site 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 78/359 reads (22%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.956); catalogued as rs377436249; called by muse, mutect2, varscan2
- AP002008.2 | n.1468-1G>T | Splice Site (SNP) | VAF 6/92 reads (7%) | catalogued as rs1432396584; called by muse, mutect2
- ATP6V0A2 | c.2044G>A p.G682R | Missense Mutation (SNP) | VAF 95/396 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs766998428, COSV57750255; called by muse, mutect2, varscan2
- EGFR | c.2320_2321insGCAACCCCCACG p.H773_V774insGNPH | In Frame Ins (INS) | VAF 40/192 reads (21%) | catalogued as COSV51771114, COSV51821649; called by mutect2, varscan2
- PARP6 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.076); catalogued as rs1451172612; called by muse, mutect2, varscan2
- PNMA3 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs781807597, COSV64722980; called by muse, mutect2
- PREX1 | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as rs1220039244; called by muse, mutect2, varscan2
- RPL5 | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs984455678, COSV100240398; called by muse, mutect2, varscan2
- RSU1 | c.695A>T p.H232L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV61708785; called by muse, mutect2
- SYT16 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs190756776, COSV101413659, COSV70855911; called by muse, mutect2, varscan2
- TST | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1266419232; called by muse, mutect2
- ACSL6 | c.817G>T p.V273L (on ENST00000379240; = p.V298L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2
- AMH | c.221_226dup p.A75_L76insRA | In Frame Ins (INS) | VAF 6/59 reads (10%) | called by mutect2, pindel
- CELSR2 | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM3B | c.2189G>A p.S730N | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF27 | c.1454G>A p.C485Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- LLCFC1 | c.344A>G p.H115R (on ENST00000458732; = p.H84R on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/357 reads (20%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LMOD2 | c.1357A>C p.K453Q | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- LRRC37A3 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 98/984 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.288); called by muse, mutect2
- OPLAH | c.2631G>C p.E877D | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA10 | c.631A>T p.I211F | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRDM5 | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX264 | c.500A>T p.Y167F | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2
- TJP2 | c.1057A>T p.I353F | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBR5 | c.7496A>G p.D2499G | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- VWDE | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ADAM33 | c.834G>A p.T278= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as rs1354748436; called by muse, mutect2
- ADGRF2 | c.2013C>T p.I671= (on ENST00000296862 / NM_001368115.2; = p.I603= on NM_153839.7) | Silent (SNP) | VAF 34/182 reads (19%) | catalogued as rs563241646, COSV57291538; called by muse, varscan2
- ARHGAP23 | c.4350G>A p.L1450= | Silent (SNP) | VAF 37/185 reads (20%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.124C>A p.R42= | Silent (SNP) | VAF 29/192 reads (15%) | called by muse, mutect2, varscan2
- DSC1 | c.2205A>C p.V735= | Silent (SNP) | VAF 17/114 reads (15%) | called by muse, varscan2
- FAM149A | c.1836G>A p.R612= (on ENST00000356371 / NM_001367768.2; = p.R321= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/430 reads (4%) | called by muse, mutect2
- FASTK | c.1581C>T p.P527= | Silent (SNP) | VAF 25/137 reads (18%) | catalogued as rs776789671; called by muse, mutect2, varscan2
- GPR162 | c.1665C>T p.S555= (on ENST00000311268 / NM_019858.2; = p.S271= on NM_014449.2) | Silent (SNP) | VAF 10/274 reads (4%) | catalogued as rs781918191, COSV51833076; called by muse, mutect2
- KMT5C | c.651C>T p.Y217= | Silent (SNP) | VAF 24/314 reads (8%) | catalogued as rs758106964, COSV55320049; called by muse, mutect2
- LILRB1 | c.96G>C p.V32= | Silent (SNP) | VAF 36/382 reads (9%) | called by muse, mutect2
- OR2T12 | c.315G>T p.L105= | Silent (SNP) | VAF 25/258 reads (10%) | called by muse, mutect2, varscan2
- PRRX1 | c.513C>T p.D171= | Silent (SNP) | VAF 37/164 reads (23%) | catalogued as rs374262561; called by muse, mutect2, varscan2
- RASSF7 | c.930C>T p.D310= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as rs752430298; called by muse, mutect2, varscan2
- SIDT2 | c.1767C>G p.L589= | Silent (SNP) | VAF 54/303 reads (18%) | catalogued as rs1287056400; called by muse, mutect2, varscan2
- SMARCA4 | c.4825C>T p.L1609= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as rs878854232; ClinVar: likely benign; called by muse, mutect2
- ALDH3A1 | c.395-264C>T | Intron (SNP) | VAF 38/103 reads (37%) | called by muse, mutect2, varscan2
- HERC2P2 | n.2622G>A | RNA (SNP) | VAF 17/437 reads (4%) | called by muse, mutect2
- NINJ2 | c.-124C>T | 5'UTR (SNP) | VAF 4/43 reads (9%) | catalogued as rs1263504865; called by muse, mutect2
- RUNX1T1 | c.1280-3854T>C | Intron (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
